Somatic mutation profile of tumor specimen TCGA-61-2104-01A (aliquot TCGA-61-2104-01A-01W-0722-08) from TCGA case TCGA-61-2104, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 53.2 years (19,432 days).
Specimen TCGA-61-2104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c501dfd5-8626-407b-a97b-3bcfbdfe52b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2104-11A (Solid Tissue Normal), aliquot TCGA-61-2104-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eca7803b-eaf8-40f1-b10f-ee7350e28fd7

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 47, Silent 18, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPG5 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 15/123 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as rs1479153773, COSV53130063; called by muse, mutect2, varscan2
- TP53 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 85/129 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AHR | c.2047C>G p.Q683E | Missense Mutation (SNP) | VAF 186/591 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV54126400; called by muse, mutect2, varscan2
- ANKFY1 | c.467A>T p.K156M | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58923107; called by muse, mutect2, varscan2
- C11orf42 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.99); catalogued as rs369121502; called by muse, mutect2, varscan2
- C19orf47 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63511179; called by muse, mutect2, varscan2
- C9orf43 | c.30C>G p.D10E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763996934, COSV55914211; called by muse, mutect2, varscan2
- CAPZB | c.32A>T p.D11V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV51652138; called by muse, mutect2
- CASS4 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs149841530, COSV64388524; called by mutect2, varscan2
- CHID1 | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs751719046, COSV60260695; called by muse, mutect2, varscan2
- DEFB112 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 160/378 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV59183136; called by muse, mutect2, varscan2
- DNAH17 | c.3963G>T p.R1321S | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV67761241; called by muse, mutect2, varscan2
- DOP1A | c.7160T>G p.I2387S | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV52286028; called by muse, mutect2, varscan2
- DPP10 | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100056179, COSV59728974; called by muse, mutect2, varscan2
- DPY19L1 | c.311G>T p.R104I | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100204383; called by muse, mutect2
- EIF2AK4 | c.2616C>A p.D872E | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV55474199; called by muse, varscan2
- EPHA5 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 49/538 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56674542, COSV99901103; called by muse, mutect2
- FBLN2 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.289); catalogued as COSV55491160; called by muse, varscan2
- FHOD3 | c.2561C>G p.P854R (on ENST00000359247 / NM_001281739.3; = p.P871R on NM_025135.5) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs1335846396, COSV57188918; called by mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- GRM3 | c.2623A>G p.T875A | Missense Mutation (SNP) | VAF 143/1191 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV100861987; called by muse, mutect2, varscan2
- KDM5B | c.3423+1G>T p.X1141_splice | Splice Site (SNP) | VAF 70/112 reads (63%) | catalogued as COSV99349851; called by muse, mutect2, varscan2
- LNX1 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99819276; called by muse, mutect2, varscan2
- MC5R | c.597C>A p.F199L | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100228869; called by muse, mutect2
- MCMBP | c.447C>G p.N149K | Missense Mutation (SNP) | VAF 264/364 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV63510709; called by muse, varscan2
- MLIP | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 774/1892 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.147); catalogued as COSV51437199; called by muse, varscan2
- MLXIPL | c.1941C>T p.T647= | Splice Region (SNP) | VAF 9/56 reads (16%) | catalogued as rs569809024, COSV57670103, COSV57670462; called by muse, mutect2, varscan2
- MNAT1 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 113/391 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs966102559, COSV54196418; called by muse, mutect2, varscan2
- MUC7 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 182/1152 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV59217838, COSV59220184; called by muse, mutect2, varscan2
- NGEF | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as COSV99887613; called by muse, mutect2
- NUP98 | c.3988C>G p.P1330A (on ENST00000359171 / NM_001365126.1; = p.P1313A on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV100261345; called by mutect2, varscan2
- OR5D16 | c.737A>T p.H246L | Missense Mutation (SNP) | VAF 332/674 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65723001; called by muse, mutect2, varscan2
- PCDHGA3 | c.1927G>T p.V643L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV53962802, COSV54035651, COSV99546627; called by muse, mutect2, varscan2
- PELI2 | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 13/338 reads (4%) | catalogued as COSV99952678; called by muse, mutect2
- PLA2G7 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 135/606 reads (22%) | catalogued as COSV51258641, COSV99221026; called by muse, mutect2, varscan2
- POU2AF1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV101260469; called by muse, mutect2
- POU2F1 | c.386A>T p.Q129L (on ENST00000541643 / NM_001365848.1; = p.Q152L on NM_002697.4) | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV54825043; called by muse, mutect2, varscan2
- RAD54L2 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV56581619; called by muse, mutect2, varscan2
- SALL1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs754846300, COSV51755108; called by muse, mutect2
- SH3TC2 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs549821020, COSV60467798; called by muse, mutect2, varscan2
- SMU1 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 47/110 reads (43%) | catalogued as COSV68140374; called by muse, mutect2, varscan2
- SORBS2 | c.2643del p.E881Dfs*37 (on ENST00000284776 / NM_021069.5; = p.E447Dfs*37 on NM_003603.6) | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | catalogued as COSV53015373; called by mutect2, pindel, varscan2
- SPAG17 | c.1805T>G p.F602C | Missense Mutation (SNP) | VAF 126/571 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60468628; called by muse, mutect2, varscan2
- SVIL | c.3991G>A p.D1331N (on ENST00000355867 / NM_021738.3; = p.D905N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV63444502; called by muse, mutect2
- TAOK3 | c.1068C>A p.S356R | Missense Mutation (SNP) | VAF 91/325 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66827801; called by muse, mutect2, varscan2
- TBC1D21 | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55996833; called by muse, mutect2, varscan2
- TNFAIP3 | c.1682A>G p.Q561R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV99396138; called by muse, mutect2, varscan2
- TRAPPC9 | c.2626C>G p.L876V | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.76); catalogued as COSV66909843; called by muse, mutect2, varscan2
- TRIB1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs34349706; called by mutect2, varscan2
- UBR4 | c.7406C>G p.T2469R | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.112); catalogued as COSV100919892; called by muse, mutect2, varscan2
- UGGT1 | c.3343G>C p.E1115Q | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52139316, COSV99390068; called by muse, mutect2
- VN1R2 | c.1003T>C p.Y335H | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as COSV100447709; called by muse, mutect2
- VWCE | c.1805G>A p.C602Y | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57115486; called by muse, mutect2, varscan2
- ZEB1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 106/399 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs866987044, COSV58048074; called by muse, varscan2
- BCLAF1 | c.766_767del p.N256Yfs*12 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | called by pindel, varscan2
- ADAMTS5 | c.1794T>C p.A598= | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as COSV53185548; called by muse, mutect2, varscan2
- AFF3 | c.645C>T p.N215= | Silent (SNP) | VAF 128/251 reads (51%) | catalogued as COSV100416973; called by muse, mutect2, varscan2
- ANKRD11 | c.2895G>A p.R965= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs760879386, COSV56372223; called by muse, mutect2, varscan2
- ARL13B | c.135C>T p.Y45= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV57401617; called by muse, mutect2, varscan2
- C1orf194 | c.195C>T p.P65= (on ENST00000369948 / NM_001245025.3; = p.P53= on NM_001122961.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1031720406, COSV64050235; called by muse, varscan2
- CAMSAP2 | c.3381C>A p.S1127= (on ENST00000236925 / NM_001297707.2; = p.S1116= on NM_203459.3) | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as COSV52677471; called by muse, mutect2, varscan2
- CRTAC1 | c.1071G>A p.Q357= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1308686717, COSV54010119; called by muse, mutect2, varscan2
- CUL9 | c.2121G>A p.Q707= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV52732483, COSV99334507; called by muse, mutect2
- DSCAM | c.2058C>G p.V686= | Silent (SNP) | VAF 110/476 reads (23%) | catalogued as COSV68036394; called by muse, mutect2, varscan2
- LRRN1 | c.969T>G p.P323= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs754238155, COSV100075925; called by muse, mutect2, varscan2
- MCF2L2 | c.1120C>T p.L374= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV61061619; called by muse, mutect2, varscan2
- NPC1L1 | c.207T>C p.D69= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV56930423; called by muse, mutect2, varscan2
- NT5C1A | c.618G>A p.L206= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs752691536, COSV52496392; called by muse, mutect2, varscan2
- OR5A1 | c.639G>A p.S213= | Silent (SNP) | VAF 261/896 reads (29%) | catalogued as rs770324514, COSV57375747; called by muse, mutect2, varscan2
- RSF1 | c.2007A>G p.L669= | Silent (SNP) | VAF 287/785 reads (37%) | catalogued as COSV100406755; called by muse, mutect2, varscan2
- SHANK1 | c.903G>T p.L301= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV53262606; called by muse, mutect2, varscan2
- SIN3A | c.294G>C p.V98= | Silent (SNP) | VAF 51/195 reads (26%) | catalogued as COSV64585080; called by muse, mutect2, varscan2
- TEKT5 | c.570C>A p.A190= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV99295725; called by muse, mutect2
